TARGET case TARGET-21-PASDKZ — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fc171729-17c1-5857-adeb-4b3af1eb1bce

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 5 years; Vital status: Dead; Days to death: 188 days.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.1 years (1,875 days); Year of diagnosis: 2008; Days to last follow up: 188 days.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML0531.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Gemtuzumab Ozogamicin.

Follow-up (1 entry)
- Days to follow up: 188 days; Days to first event: 188 days; First event: Death; Year of follow up: 2009.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Positive.
- KMT2A translocation: Negative.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- NUP98–NSD1 fusion: Positive.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- WT1 mutation, nos: Positive.
- Day 0: Leukocytes 53.5 ×10³/µL; Blast Count 47%; Bone Marrow blast count 73.2%.
- Minimal Residual Disease (Flow Cytometry): Positive.

Biospecimens (4 samples)
- Sample TARGET-21-PASDKZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-21-PASDKZ-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Sample TARGET-21-PASDKZ-15A: Sample type: Fibroblasts from Bone Marrow Normal; Tissue type: Normal; Specimen type: Fibroblasts from Bone Marrow.
- Sample TARGET-21-PASDKZ-41A: Sample type: Blood Derived Cancer - Bone Marrow, Post-treatment; Tissue type: Tumor; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_Discovery_20230720.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 188
- WBC at Diagnosis: 53.5
- Bone marrow leukemic blast percentage (%): 73.2
- Peripheral blasts (%): 47
- CNS disease: No
- Chloroma: No
- FAB Category: M4
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: No
- Minus Y: No
- Minus X: No
- Cytogenetic Complexity: 0
- Primary Cytogenetic Code: Normal
- ISCN: 46,XX[20]
- FLT3/ITD positive?: Yes
- FLT3/ITD allelic ratio: 0.61
- FLT3 PM: No
- NPM mutation: No
- CEBPA mutation: No
- WT1 mutation: Yes
- MRD at end of course 1: Yes
- MRD % at end of course 1: 34
- CR status at end of course 1: not in CR
- CR status at end of course 2: not in CR
- Risk group: High Risk
- Gene Fusion: NUP98-NSD1
- Gemtuzumab ozogamicin treatment: Gentuzumab ozogamicin treatment
- Refractory Timepoint sent for Induction Failure Project: EOI I
